Somatic mutation profile of tumor specimen TCGA-E1-A7Z3-01A (aliquot TCGA-E1-A7Z3-01A-11D-A34J-08) from TCGA case TCGA-E1-A7Z3, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.0 years (11,330 days).
Specimen TCGA-E1-A7Z3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd7095fe-5ac4-405c-8383-3d4ef6da898a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7Z3-10A (Blood Derived Normal), aliquot TCGA-E1-A7Z3-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c52a653-6c0e-4d36-93d3-476bd345f89b

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 3, In Frame Del 2, Intron 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 16/48 reads (33%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ARL6 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV60117797; called by muse, varscan2
- CDC5L | c.1855A>C p.N619H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65176248; called by muse, mutect2, varscan2
- COX7B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV63782923, COSV63783312; called by muse, mutect2
- CRYBG2 | c.4704C>G p.I1568M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV100366846; called by muse, mutect2, varscan2
- DNAJC2 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.446); catalogued as COSV50786387; called by muse, mutect2, varscan2
- F13B | c.1511A>G p.Q504R | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66374237; called by muse, mutect2, varscan2
- JCAD | c.1549A>G p.R517G | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100948509; called by muse, mutect2
- LIMD1 | c.208_209del p.L70Afs*5 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs1373475683; called by pindel, varscan2
- MYO1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769355024, COSV55652399; called by muse, mutect2, varscan2
- MYO1E | c.2653A>G p.N885D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55688882; called by muse, mutect2, varscan2
- ROBO2 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59915077; called by muse, mutect2, varscan2
- UNC79 | c.1991A>G p.E664G (on ENST00000393151 / NM_001346218.2; = p.E487G on NM_020818.5) | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99829108; called by muse, mutect2
- VPS13A | c.9043G>T p.D3015Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100653177; called by muse, mutect2
- ZNF470 | c.1014A>C p.K338N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57969238; called by muse, mutect2, varscan2
- ATRX | c.6812_6815del p.R2271Kfs*14 | Frame Shift Del (DEL) | VAF 64/278 reads (23%) | called by pindel, varscan2
- DNAJC13 | c.280_282del p.L94del | In Frame Del (DEL) | VAF 10/45 reads (22%) | called by pindel, varscan2
- PDE8B | c.1566_1567del p.F523Yfs*2 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by pindel, varscan2
- ETHE1 | c.291C>T p.G97= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99417421; called by muse, mutect2
- KHDC4 | c.861A>G p.R287= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs762628463, COSV100850836; called by muse, mutect2, varscan2
- SOX3 | c.663T>C p.D221= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100983736; called by muse, mutect2, varscan2
- TRIP11 | c.4665A>G p.Q1555= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV99970951; called by muse, mutect2
- ANKRD20A5P | n.298A>T | RNA (SNP) | VAF 12/297 reads (4%) | called by muse, mutect2
- UGT1A6 | c.862-23291G>A | Intron (SNP) | VAF 70/240 reads (29%) | catalogued as rs745945267, COSV59384944; called by muse, mutect2, varscan2
